Surgical pathology report (de-identified scan), TCGA case TCGA-FP-8210, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-8210-01A (Primary Tumor).

[page 1 of 2]
✓ TEST: Surgical Pathology

Collected Date & Time [REDACTED]

Result Name	Results	Units	Reference Range
✓ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis
Gastric adenocarcinoma
Post-Op Diagnosis
Nothing indicated
Clinical History
Nothing indicated
Gross Description:

Received in a single container labeled [REDACTED] - partial gastrectomy" is a portion of recognizable distal stomach measuring 15.4 cm along the greater curvature and 9.3 cm along the lesser curvature. The specimen has been previously opened along the lesser curvature. There is a minimal amount of lesser curvature adipose tissue as well as a small amount of greater curvature tissue as well as a 31.3 x 29.2 x up to 1.0 cm sheet of attached recognizable omentum on the greatest curvature. The serosa is smooth and tan brown with a 3.2 x 2.5 cm gray white fibrotic plaque noted at a point 2.0 cm from the distal margin on the anterior aspect extending toward the greater curvature. The gastric wall is up to 1.0 cm edematous and fibrotic. The lumen is lined by cobblestoned gray tan mucosa with preservation of normal rugation. At a point 1.0 cm from the distal margin there is a previously partially sectioned fairly well defined 2.6 x 2.5 cm lobulated centrally ulcerated gray tan plaque like lesion which extends to both the anterior and posterior aspects as well as the greater curvature. This appears to focally extend to the lesser curvature. On sectioning this lesion has a gritty gray tan fibrotic cut surface measuring up to 1.6 cm in thickness. The lesion appears to extend to but not through the serosa in the majority of the specimen with a few focal areas of apparent extension in the greater curvature in the posterior aspect. On sectioning the lesser curvature and greater curvature adipose tissue reveals several well defined and poorly defined gray tan to yellow nodules measuring up to 1.4 cm in greatest dimension. On sectioning the largest nodules have fleshy gray tan cut surfaces. On sectioning the omentum reveals a few areas of gray tan indurated fibrosis which are poorly defined measuring up to 0.4 cm. Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - greater curvature adipose tissue proximal; B - anterior margin proximal; C - lesser curvature margin proximal; D - posterior margin proximal; E - greater curvature margin distal; F - anterior margin distal; G - lesser curvature margin distal; H - posterior margin distal; I through L - lesion to greater curvature; M - lesion anterior wall; N - lesion lesser curvature; O - lesion posterior wall; P - representative greater curvature mucosa; Q - anterior mucosa; R - lesser curvature mucosa; S - posterior mucosa; T - largest nodule from lesser curvature adipose tissue bisected; U - whole smaller nodules from lesser curvature adipose tissue; V and W - individual nodules from greater curvature adipose tissue bisected; X through Z - whole smaller nodules from greater curvature adipose tissue; AA through CC - representative omentum.

Microscopic Description:

See diagnosis.

Final Diagnosis

Distal stomach, partial gastrectomy:

Ulcerated infiltrative poorly differentiated adenocarcinoma with focal signet rings.

Diffuse type adenocarcinoma of Lauren.

Tumor size: 2.6 x 2.5 cm

Tumor extends to inked serosal margin of resection.

Tumor is located mainly in antrum.

Lymphovascular space identified.

Path Stage: T3N1Mx

[page 2 of 2]
Perineural space identified.

Multiple foci of tumor in perigastric adipose tissue and omentum.

Proximal margin of resection is negative.

Tumor is 1.0 cm from distal margin of resection.

Radial margin (serosal) is positive.

Three of 23 lymph nodes is positive.

One positive lymph node has extracapsular extension.

Remainder of stomach with focal intestinal metaplasia, acute and chronic inflammation, and reactive changes.

Stage: T3, N1

Comments

This test has been finalized at the Campus.

M.D.

Source: NCI Genomic Data Commons file e63827aa-b84a-43f4-815e-cfdcbde13c5f (TCGA-FP-8210.E5CB3F23-7CF4-402F-8072-03766043B04A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).